Somatic mutation profile of tumor specimen TCGA-EB-A4IS-01A (aliquot TCGA-EB-A4IS-01A-21D-A25O-08) from TCGA case TCGA-EB-A4IS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.5 years (28,315 days).
Specimen TCGA-EB-A4IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9144d5b9-d4d2-432a-8cf3-0bdef3dfdbf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4IS-10A (Blood Derived Normal), aliquot TCGA-EB-A4IS-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f5a299-afb2-48c9-8231-25777941a7ff

The open-access MAF lists 673 somatic variants for this specimen: 412 protein-altering or splice-affecting, 243 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 378, Silent 243, Nonsense Mutation 23, Intron 6, Splice Region 5, Splice Site 4, 5'Flank 4, RNA 4, 3'UTR 3, Frame Shift Del 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/128 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.12844C>T p.R4282* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as rs1057517992, CM146829, COSV56428217; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- THSD7B | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55688858; called by muse, mutect2, varscan2
- A2ML1 | c.2903G>A p.S968N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.356); catalogued as COSV55292558, COSV99075349; called by muse, mutect2, varscan2
- AATK | c.3034G>A p.E1012K (on ENST00000326724 / NM_001080395.3; = p.E909K on NM_004920.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58368400; called by muse, mutect2
- ABCA5 | c.4375C>T p.P1459S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421625170, COSV67017374; called by muse, mutect2, varscan2
- ABCB4 | c.1748C>A p.T583N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55936918; called by muse, mutect2
- ABCD2 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV58051267, COSV58051917; called by muse, mutect2, varscan2
- ABHD13 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV65535080; called by muse, mutect2, varscan2
- ABTB2 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV54390471; called by muse, mutect2, varscan2
- AC090517.4 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs1257887757, COSV50997883; called by muse, mutect2
- ACOT8 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54170096; called by muse, mutect2, varscan2
- ACSBG2 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99397321; called by muse, mutect2, varscan2
- ADAM33 | c.1312-1G>A p.X438_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV62935324; called by muse, mutect2, varscan2
- ADAMDEC1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs760760973, COSV56474739; called by muse, mutect2, varscan2
- ADAMTS17 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1176129095, COSV51484173; called by muse, mutect2, varscan2
- ADAMTS18 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV51417659, COSV51419530; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV54453732; called by muse, mutect2, varscan2
- ADARB2 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs373191144; called by muse, mutect2, varscan2
- ADGRB3 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53249396; called by muse, mutect2, varscan2
- ADGRG4 | c.6938G>A p.R2313K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1468956889, COSV54950764; called by muse, mutect2, varscan2
- ADGRV1 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); catalogued as CM0911267, COSV67987929; called by muse, mutect2
- ADGRV1 | c.9439C>T p.R3147* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs769681955, COSV67985825; called by muse, mutect2, varscan2
- ADIPOR1 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV61851764; called by muse, mutect2
- AGBL5 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1383259123, COSV59936872; called by muse, mutect2
- AGO3 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV55794237, COSV99867882; called by muse, mutect2, varscan2
- AGPAT1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs1423578165, COSV61247964; called by muse, mutect2, varscan2
- AHNAK2 | c.2954C>T p.S985F | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs776663755, COSV60920849; called by muse, varscan2
- AKAP11 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV50297835; called by muse, mutect2, varscan2
- AL163636.1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.028); catalogued as rs1555346364, CM1413596, COSV59012476; called by muse, mutect2, varscan2
- AMBN | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); catalogued as COSV59826784, COSV59827788; called by muse, mutect2, varscan2
- AMY1A | c.879G>A p.K293= | Splice Region (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100915781; called by mutect2, varscan2
- AMY2A | c.516C>T p.V172= | Splice Region (SNP) | VAF 18/160 reads (11%) | catalogued as COSV101340626; called by mutect2, varscan2
- ANK2 | c.6913G>A p.E2305K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as COSV100000840; called by muse, mutect2
- ANK3 | c.9596C>T p.P3199L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV55088433; called by muse, mutect2, varscan2
- ANK3 | c.9595C>T p.P3199S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV99779323; called by muse, mutect2, varscan2
- ANK3 | c.5299T>G p.F1767V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.09); catalogued as COSV55063946; called by muse, mutect2, varscan2
- ANO1 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1565232740, COSV100303917, COSV60285960; called by muse, mutect2, varscan2
- ANO3 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV56795588; called by muse, mutect2, varscan2
- APBA3 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57462938; called by muse, mutect2, varscan2
- APOB | c.10988G>A p.G3663E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs267599179, COSV51940144; called by muse, mutect2, varscan2
- APPL1 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55701503; called by muse, mutect2, varscan2
- ARHGAP25 | c.917A>C p.N306T (on ENST00000409202 / NM_001007231.3; = p.N298T on NM_014882.3) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54903826; called by muse, mutect2
- ARHGEF10L | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51434517; called by muse, mutect2, varscan2
- ASXL3 | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs770577167, COSV52461969, COSV99327010; called by muse, mutect2, varscan2
- ATP2C1 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs1157144837, CM020639, COSV60757984; called by muse, mutect2, varscan2
- ATP8A1 | c.3400G>A p.G1134R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52538329; called by muse, mutect2, varscan2
- ATP8B3 | c.3245C>T p.A1082V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100034281; called by muse, mutect2, varscan2
- B3GAT3 | c.829C>G p.R277G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs149098151, COSV53883054; called by muse, mutect2, varscan2
- BMF | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV55019257; called by muse, mutect2, varscan2
- BMPR1B | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99215630; called by muse, mutect2, varscan2
- BOD1L1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV50019955; called by muse, mutect2, varscan2
- BRDT | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100746581, COSV62865516; called by muse, mutect2
- BTK | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58120951; called by muse, mutect2, varscan2
- C2CD2L | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60884228; called by muse, mutect2, varscan2
- C6 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1416773804, COSV54712077; called by muse, mutect2, varscan2
- CACNA1E | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1323731533, COSV62401431; called by muse, mutect2, varscan2
- CACNA1H | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs780522034, COSV100671778; called by muse, mutect2, varscan2
- CACNA2D1 | c.2858G>A p.R953Q (on ENST00000356253 / NM_001366867.1; = p.R941Q on NM_000722.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs991607267, COSV100666383; called by muse, mutect2, varscan2
- CAPZA3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868744411, COSV56849081, COSV56850605; called by muse, mutect2, varscan2
- CAT | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53811610; called by muse, mutect2, varscan2
- CCAR2 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52385117; called by muse, mutect2, varscan2
- CCDC92 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.23); catalogued as COSV53020224; called by muse, mutect2, varscan2
- CCP110 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66817180; called by muse, mutect2, varscan2
- CDH16 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1165275272, COSV55335574, COSV55340120; called by muse, mutect2, varscan2
- CDH2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.213); catalogued as rs202198632, COSV52273863; called by muse, mutect2, varscan2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, mutect2, varscan2
- CDKN2AIP | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56627346; called by muse, mutect2, varscan2
- CEP162 | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100002612; called by muse, mutect2, varscan2
- CFAP92 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373579452, COSV54047833; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CFHR5 | c.1482T>G p.N494K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.604); catalogued as COSV56823261; called by muse, mutect2, varscan2
- CFTR | c.4337G>A p.R1446K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV50063616, COSV99136555; called by muse, mutect2, varscan2
- CHD6 | c.7060C>T p.P2354S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV64691895; called by muse, mutect2, varscan2
- CHST1 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); catalogued as rs1359494864, COSV57324133; called by muse, mutect2, varscan2
- CHST10 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs367887748, COSV51804118; called by muse, mutect2, varscan2
- CIZ1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52972576; called by muse, mutect2
- CLUH | c.1448C>T p.T483M (on ENST00000435359; = p.T521M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs950000630, COSV70927639; called by muse, mutect2, varscan2
- CNKSR1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64163530; called by muse, mutect2, varscan2
- CNR1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as rs1189891827, COSV62988406; called by muse, mutect2, varscan2
- CNTN2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs199539011; called by muse, mutect2, varscan2
- CNTN6 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63176583; called by muse, mutect2, varscan2
- CNTNAP5 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV70485473, COSV70491856; called by muse, mutect2
- COBLL1 | c.2455G>A p.E819K (on ENST00000392717; = p.E781K on NM_014900.5) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52069888; called by muse, mutect2, varscan2
- COG4 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60423387; called by muse, mutect2, varscan2
- COG4 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs376820609, COSV56785709; called by muse, mutect2, varscan2
- COG4 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100091589; called by muse, mutect2, varscan2
- COL22A1 | c.3023G>A p.G1008E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs1170339480, COSV57321783, COSV57342932; called by muse, mutect2, varscan2
- COL4A5 | c.3169G>A p.G1057R | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960384, COSV60364120; called by muse, mutect2, varscan2
- COPA | c.3541C>T p.P1181S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV54104292; called by muse, mutect2, varscan2
- CORO1A | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV54631436, COSV54632061; called by muse, mutect2, varscan2
- CYLD | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV61095466; called by muse, mutect2, varscan2
- CYP4F12 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61174440; called by muse, mutect2
- CYRIA | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62864651; called by muse, mutect2, varscan2
- DDI1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs115891405, COSV56382111; called by muse, mutect2, varscan2
- DENND2A | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as rs913049832, COSV52052565; called by muse, mutect2
- DEUP1 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV53213351; called by muse, mutect2, varscan2
- DHX36 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV57674019; called by muse, mutect2, varscan2
- DLEC1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV57301455; called by muse, mutect2, varscan2
- DMKN | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV60087128; called by muse, mutect2, varscan2
- DNAH2 | c.10648G>A p.E3550K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs755405973, COSV66721115; called by muse, mutect2, varscan2
- DNAH6 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV52866601; called by muse, mutect2, varscan2
- DNAH9 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV52356173, COSV99303796; called by muse, mutect2
- DOCK11 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV52241406; called by muse, mutect2, varscan2
- DPY19L2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs1440778977, COSV60544088; called by muse, mutect2, varscan2
- DSC1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57147119; called by muse, mutect2, varscan2
- DSC3 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV64573591; called by muse, mutect2, varscan2
- DUXA | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs777400385, COSV73729530; called by muse, mutect2, varscan2
- DYNAP | c.593C>T p.S198F (on ENST00000321600; = p.S172F on NM_173629.3) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV58666529; called by muse, mutect2, varscan2
- DZIP3 | c.2200-1G>A p.X734_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV64312542; called by muse, mutect2
- ECEL1 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1400453983, COSV58812910; called by mutect2, varscan2
- EEF1A1 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as COSV58549871; called by muse, mutect2, varscan2
- EFS | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs764112476, COSV53732889; called by muse, mutect2
- ELAVL2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.113); catalogued as COSV56364104, COSV56367920; called by muse, mutect2, varscan2
- EPG5 | c.4676T>C p.V1559A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56351356; called by muse, mutect2, varscan2
- EPPK1 | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs368221168, COSV73261550; called by muse, mutect2
- EPPK1 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1554661529, COSV73261551; called by muse, mutect2, varscan2
- ERBB4 | c.1870G>T p.G624W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53544533; called by muse, mutect2, varscan2
- ERBB4 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV53544548; called by muse, mutect2, varscan2
- EXOC7 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777519540, COSV58742532; called by muse, mutect2, varscan2
- FAM120B | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV53005263; called by muse, mutect2, varscan2
- FAM47A | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as rs774509523, COSV60497662; called by muse, mutect2, varscan2
- FAM71B | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV57229633; called by muse, mutect2, varscan2
- FANCE | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV57690244; called by muse, mutect2, varscan2
- FAT4 | c.8142G>A p.M2714I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58673280; called by muse, mutect2, varscan2
- FBN1 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.021); catalogued as COSV57320394; called by muse, mutect2, varscan2
- FBXO40 | c.1917C>T p.I639= | Splice Region (SNP) | VAF 28/134 reads (21%) | catalogued as COSV57524963; called by muse, mutect2, varscan2
- FCGBP | c.6661G>A p.D2221N | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209163607; called by muse, mutect2, varscan2
- FER1L6 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV67550778; called by muse, mutect2, varscan2
- FLRT1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.443); catalogued as COSV99734510; called by mutect2, varscan2
- FLT1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56731224, COSV56735070; called by muse, mutect2, varscan2
- FMR1NB | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1034123999, COSV65071138; called by muse, mutect2, varscan2
- GABRA4 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV51930020; called by muse, mutect2, varscan2
- GALNT9 | c.1150C>T p.P384S (on ENST00000328957 / NM_001122636.2; = p.P18S on NM_021808.3) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV61100204; called by muse, varscan2
- GATM | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67540623, COSV99063814; called by muse, mutect2, varscan2
- GH2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.369); catalogued as COSV60427098, COSV99068058; called by muse, mutect2, varscan2
- GNB5 | c.1097A>C p.H366P (on ENST00000261837 / NM_016194.4; = p.H324P on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV55899842; called by muse, mutect2, varscan2
- GPR119 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99358594; called by muse, mutect2, varscan2
- GPR50 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV54440019; called by muse, mutect2, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRID2 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56220788, COSV56257737; called by muse, mutect2, varscan2
- GRIK2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185495338, COSV59725673; called by muse, mutect2
- GRM1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51176350; called by muse, mutect2, varscan2
- GRM3 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV64473982; called by muse, mutect2, varscan2
- GRM8 | c.2393T>A p.I798N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58836498; called by muse, mutect2, varscan2
- GTF2IRD1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV99734406; called by muse, mutect2
- GUF1 | c.1150T>G p.S384A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs773206700, COSV55783208; called by muse, mutect2, varscan2
- HELZ2 | c.6439C>T p.P2147S (on ENST00000467148 / NM_001037335.2; = p.P1578S on NM_033405.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV101427543; called by muse, mutect2, varscan2
- HEPH | c.2309T>C p.L770P (on ENST00000343002; = p.L503P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57965955; called by muse, mutect2, varscan2
- HERC1 | c.4801G>C p.G1601R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV71248501; called by muse, mutect2
- HIPK4 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV52521938; called by muse, mutect2, varscan2
- HJV | c.1079C>T p.S360F (on ENST00000336751 / NM_213653.4; = p.S247F on NM_145277.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV60951266; called by muse, mutect2, varscan2
- HK3 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213460443, COSV52841425; called by muse, mutect2, varscan2
- HMCN1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54910069; called by muse, mutect2, varscan2
- HMCN1 | c.8197A>C p.K2733Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); catalogued as COSV54910082; called by muse, mutect2, varscan2
- HS6ST3 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65011698; called by muse, mutect2, varscan2
- HTR4 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.846); catalogued as COSV100087658; called by muse, mutect2, varscan2
- IFNG | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs926987512, COSV57490688; called by muse, mutect2
- IGF2R | c.7436C>T p.S2479F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV63630008; called by mutect2, varscan2
- IGHV3-21 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.704); catalogued as rs782312696; called by muse, mutect2, varscan2
- IGKV1-12 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs769293675; called by muse, mutect2, varscan2
- IMPDH1 | c.539C>T p.P180L (on ENST00000470772 / NM_001142573.2; = p.P266L on NM_000883.4) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV58316598; called by muse, mutect2, varscan2
- IQCN | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs373950102, COSV66575029; called by muse, mutect2, varscan2
- IRF6 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV54214204; called by muse, mutect2, varscan2
- ITGA8 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV65224226; called by muse, mutect2, varscan2
- JPH2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV65904132; called by muse, mutect2, varscan2
- KATNAL2 | c.506G>A p.R169K (on ENST00000356157 / NM_001353899.1; = p.R97K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV55301392; called by muse, mutect2, varscan2
- KBTBD3 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV73241479; called by muse, mutect2, varscan2
- KCNB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV73050947, COSV73053233; called by muse, mutect2
- KCNG4 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57583974; called by muse, mutect2, varscan2
- KCNG4 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376976; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KCNH6 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV59004485; called by muse, mutect2, varscan2
- KCNJ6 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55716433; called by muse, mutect2, varscan2
- KCNQ5 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV59665944; called by muse, mutect2, varscan2
- KIAA0232 | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56926482; called by muse, mutect2, varscan2
- KIF13A | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs1038727795, COSV52453880; called by muse, mutect2
- KIF26B | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs749916160, COSV63644058; called by muse, mutect2, varscan2
- KIR3DL2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1266629069, COSV54389697, COSV99551857; called by muse, mutect2, varscan2
- KL | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66308462; called by muse, mutect2, varscan2
- KL | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs377122431; called by muse, mutect2, varscan2
- KLHDC9 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs989609793, COSV63509915; called by muse, mutect2, varscan2
- KLHL18 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51746500; called by muse, mutect2
- KLHL40 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs1333354759, COSV55135175; called by muse, mutect2, varscan2
- KMT5B | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs140037372; called by muse, mutect2, varscan2
- KMT5B | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100430073, COSV58563337; called by muse, mutect2, varscan2
- KRT74 | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs369367487, COSV59772064; called by muse, mutect2, varscan2
- KRTAP5-6 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV66289274; called by muse, mutect2, varscan2
- LAMA3 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs922313361, COSV58071440; called by muse, mutect2, varscan2
- LCT | c.2254C>T p.L752F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51551677; called by muse, mutect2, varscan2
- LGSN | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs778586283, COSV101040483, COSV65726977; called by muse, mutect2, varscan2
- LIME1 | c.760T>G p.Y254D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55511266; called by muse, mutect2, varscan2
- LMO7 | c.2377G>A p.D793N (on ENST00000357063; = p.D474N on NM_005358.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV58530803, COSV58539874; called by muse, mutect2, varscan2
- LRP1B | c.4865G>A p.W1622* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV67236116; called by muse, mutect2, varscan2
- LRP4 | c.5344C>T p.P1782S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV66136487; called by muse, mutect2
- LRRC20 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs529412069, COSV62938538; called by muse, mutect2, varscan2
- LRRC4C | c.1887G>A p.M629I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV53419087; called by muse, mutect2, varscan2
- LRRC66 | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV58634531; called by muse, mutect2, varscan2
- LY96 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53025742; called by muse, mutect2, varscan2
- MAGI1 | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV58318826, COSV58332100; called by muse, mutect2
- MAN1B1 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65371464; called by muse, mutect2
- MARVELD3 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as rs768257715, COSV51703984, COSV51704500; called by muse, mutect2, varscan2
- MCF2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58487367; called by muse, mutect2, varscan2
- MCM3AP | c.5037G>A p.G1679= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as rs1432849960, COSV52441145; called by muse, mutect2, varscan2
- MCTP1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56520959; called by muse, mutect2, varscan2
- MGAM | c.1942C>T p.L648F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV72074603; called by muse, mutect2, varscan2
- MIB1 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as rs1377877643, COSV55091601; called by muse, mutect2, varscan2
- MIS18BP1 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60371479; called by muse, mutect2, varscan2
- MLLT1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV99397957; called by muse, mutect2, varscan2
- MLLT1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99397959; called by muse, mutect2, varscan2
- MLST8 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 30/145 reads (21%) | catalogued as COSV57029138; called by muse, mutect2, varscan2
- MMRN1 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs756839921, COSV53338762; called by muse, mutect2, varscan2
- MS4A6A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60619670; called by muse, varscan2
- MTMR14 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs763236480, COSV56005620; called by muse, mutect2, varscan2
- MUC16 | c.21452C>T p.S7151L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.068); catalogued as COSV67474570; called by muse, mutect2, varscan2
- MUC16 | c.7933C>T p.P2645S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV67474578; called by muse, mutect2, varscan2
- MUC17 | c.3898A>T p.T1300S | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs375644852, COSV60289929; called by muse, mutect2, varscan2
- MUC17 | c.8728C>T p.P2910S | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.857); catalogued as COSV60292414; called by muse, mutect2, varscan2
- MUC2 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); catalogued as rs746895360; called by muse, mutect2, varscan2
- MUC4 | c.2320C>T p.H774Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs773746923, COSV62158703; called by muse, mutect2, varscan2
- MYH8 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV67967191; called by muse, mutect2, varscan2
- MYO18B | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | catalogued as rs1390120011, COSV59137956; called by muse, mutect2, varscan2
- MYO3A | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.14); catalogued as COSV56335619; called by muse, mutect2, varscan2
- NAT10 | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV57664550; called by muse, mutect2, varscan2
- NCOR1 | c.1082+2T>G p.X361_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51980231, COSV51988235; called by muse, mutect2, varscan2
- NEB | c.13738G>A p.E4580K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as rs762135216, COSV51427481; called by muse, mutect2, varscan2
- NELL1 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1322267788, COSV54278873, COSV54293523; called by mutect2, varscan2
- NF1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as CD116616, COSV62207360, COSV62220620; called by muse, mutect2, varscan2
- NFE2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV56456221; called by muse, mutect2, varscan2
- NIPAL1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55006476, COSV55006837; called by muse, mutect2
- NLRP5 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66761986; called by muse, mutect2, varscan2
- NOBOX | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1234727163, COSV56195235; called by muse, mutect2, varscan2
- NOP53 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV54409221; called by muse, mutect2, varscan2
- NOP56 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV61390386; called by muse, mutect2, varscan2
- NPAS4 | c.1816C>G p.P606A | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60651052; called by muse, mutect2
- NPC1 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV52579870; called by muse, mutect2, varscan2
- NRXN1 | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58463056; called by muse, mutect2
- NSUN7 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773389446, COSV57274610; called by muse, mutect2, varscan2
- NUDT2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60678694; called by muse, mutect2, varscan2
- NUP62 | c.1463T>A p.I488N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs755832145, COSV61312497; called by muse, mutect2, varscan2
- NUTM1 | c.3112A>G p.S1038G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV59217376; called by muse, mutect2, varscan2
- ODR4 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55217568; called by muse, mutect2, varscan2
- OR13J1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV65069934; called by muse, mutect2, varscan2
- OR2M7 | c.593T>G p.V198G | Missense Mutation (SNP) | VAF 98/325 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV58738952; called by muse, mutect2
- OR4C3 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV60587159; called by muse, mutect2, varscan2
- OR4C6 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV58604690, COSV58606437; called by muse, mutect2, varscan2
- OR52B2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs751797878, COSV73209390; called by mutect2, varscan2
- OR52E2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100384809, COSV58612847; called by muse, mutect2
- OR5T2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57587719; called by muse, mutect2, varscan2
- OR6N2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1558035470, COSV59411511, COSV59411841; called by muse, mutect2, varscan2
- OR7G3 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV59640500; called by muse, mutect2, varscan2
- PAM | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs912577593, COSV57214931; called by muse, mutect2, varscan2
- PAQR9 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV61418462; called by muse, mutect2, varscan2
- PAWR | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1485892110, COSV60923606; called by muse, mutect2, varscan2
- PCDHA5 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as COSV65353473, COSV65357418; called by muse, mutect2, varscan2
- PCDHB2 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV50608943; called by muse, mutect2, varscan2
- PCLO | c.7862C>T p.S2621F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV61642916; called by muse, mutect2, varscan2
- PDCD10 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868732450, COSV67102093, COSV67103181; called by muse, mutect2, varscan2
- PDZD2 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56861754; called by muse, mutect2, varscan2
- PIK3C2G | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs747191371, COSV99850841; called by muse, mutect2
- PKD1 | c.7417G>A p.G2473R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755488448, COSV51918772; called by muse, mutect2
- PLAG1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV57612513; called by muse, mutect2, varscan2
- PLAG1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV57612530; called by muse, mutect2, varscan2
- PLCZ1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs755975788, COSV56854359; called by muse, mutect2, varscan2
- PMCH | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV59674392; called by muse, mutect2, varscan2
- PNPLA1 | c.916G>A p.G306R (on ENST00000394571 / NM_001374623.1; = p.G211R on NM_173676.2) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs536510288, COSV57235267; called by muse, mutect2, varscan2
- POLQ | c.7733T>A p.I2578K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51754412; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53453570; called by muse, mutect2, varscan2
- PPFIBP2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV55078382; called by muse, mutect2
- PPP1R16B | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs756077958, COSV55379206; called by muse, mutect2, varscan2
- PRKACB | c.757T>A p.S253T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV65759924; called by muse, mutect2, varscan2
- PRRC2A | c.4060C>T p.P1354S | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs752664032, COSV65687295, COSV65689042; called by muse, mutect2, varscan2
- PTCH2 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64711563; called by muse, mutect2
- PTGER3 | c.1117G>A p.E373K (on ENST00000370932; = p.G373E on NM_198716.2) | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV63392110; called by muse, mutect2, varscan2
- PTPRC | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV61412107, COSV61422978; called by muse, mutect2, varscan2
- PYHIN1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63722860, COSV63723586; called by muse, mutect2, varscan2
- QSER1 | c.701C>T p.S234F (on ENST00000399302; = p.S363F on NM_001076786.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV67900964; called by muse, mutect2, varscan2
- RASIP1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV55805730, COSV55806045; called by muse, mutect2, varscan2
- RBL2 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV50880190; called by muse, mutect2, varscan2
- RBM27 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.969); catalogued as COSV99505985; called by muse, mutect2, varscan2
- RERG | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57002224; called by muse, mutect2, varscan2
- REXO1 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV50080307; called by muse, mutect2, varscan2
- RFPL2 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as COSV50712183; called by muse, mutect2, varscan2
- RIN3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53650635; called by muse, mutect2, varscan2
- RIOK2 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51613268; called by muse, mutect2, varscan2
- ROS1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as rs747794595, COSV63853737; called by muse, mutect2, varscan2
- RP1 | c.4831C>T p.P1611S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs201519839; called by muse, mutect2, varscan2
- RPL22 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV52378164, COSV52379347; called by muse, mutect2, varscan2
- RPTN | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as COSV60167685; called by muse, mutect2
- RTN3 | c.1949C>T p.S650F (on ENST00000377819 / NM_001265589.2; = p.S631F on NM_201428.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58027420; called by muse, mutect2, varscan2
- RTN4IP1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as rs148788441; called by muse, mutect2
- RWDD3 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1356977014, COSV55722244; called by muse, mutect2, varscan2
- RYR2 | c.3248A>T p.E1083V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV63692168; called by muse, mutect2
- S100A12 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64199195; called by muse, mutect2, varscan2
- SALL3 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1208497941, COSV73306152; called by muse, mutect2, varscan2
- SAMD3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV63717340; called by muse, mutect2, varscan2
- SCAF1 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55868661; called by muse, mutect2
- SCARB2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337309508, COSV53669112; called by muse, mutect2, varscan2
- SCN10A | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs867785573, COSV71860172; called by muse, mutect2
- SCN3A | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51813854; called by muse, mutect2, varscan2
- SDE2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55251651; called by muse, mutect2, varscan2
- SEC14L3 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354696699, COSV53178203; called by muse, mutect2, varscan2
- SEMA3D | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs757282057, COSV52392787; called by muse, mutect2, varscan2
- SERAC1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275339909, COSV65596971; called by muse, mutect2, varscan2
- SHC3 | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65439101; called by muse, mutect2, varscan2
- SHOC1 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV59503264; called by muse, mutect2, varscan2
- SLC18A1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52351564; called by muse, mutect2
- SLC25A52 | c.290C>T p.P97L (on ENST00000672005; = p.P87L on NM_001034172.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV52502836; called by muse, mutect2, varscan2
- SLC35A5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.061); catalogued as COSV53727148; called by muse, mutect2
- SLC35F4 | c.614G>A p.W205* (on ENST00000339762 / NM_001352015.2; = p.W169* on NM_001206920.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100334103, COSV60265359; called by muse, mutect2, varscan2
- SLC4A8 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60654471; called by muse, mutect2, varscan2
- SLC9C1 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99997685; called by muse, mutect2
- SLFN13 | c.1204C>G p.P402A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV53194030; called by muse, mutect2, varscan2
- SMG7 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV61629974; called by muse, mutect2, varscan2
- SNPH | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756472276, COSV60589775; called by muse, mutect2, varscan2
- SORCS3 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs1025018871, COSV63795847; called by muse, mutect2, varscan2
- SOX10 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM119676, CM119679, COSV62806811; called by muse, mutect2, varscan2
- SPATA31D1 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.316); catalogued as COSV100782374, COSV61193257; called by muse, mutect2, varscan2
- SPEN | c.4646A>T p.K1549I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV65363514; called by muse, mutect2, varscan2
- SPHKAP | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV60870653; called by muse, mutect2, varscan2
- SPINK5 | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV56256587; called by muse, mutect2
- SPTA1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63755169; called by muse, mutect2
- SRSF2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV57973368; called by muse, mutect2, varscan2
- ST8SIA5 | c.312G>A p.K104= | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100164617; called by muse, mutect2, varscan2
- ST8SIA5 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100164618, COSV100164875; called by muse, mutect2
- STK31 | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63457178; called by muse, mutect2, varscan2
- SYMPK | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773911989, COSV55612702; called by muse, mutect2, varscan2
- SYNE1 | c.16046C>T p.P5349L (on ENST00000367255 / NM_182961.4; = p.P5278L on NM_033071.3) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55013659; called by muse, mutect2, varscan2
- SYNJ1 | c.4166C>T p.P1389L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100449145; called by muse, mutect2, varscan2
- SYT17 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV62545557; called by muse, mutect2, varscan2
- TAC4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as rs201147441, COSV58003643; called by muse, mutect2, varscan2
- TAF1L | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs34787787, COSV54263729; called by muse, mutect2, varscan2
- TAF2 | c.2393T>G p.M798R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1425713518, COSV65418767; called by muse, mutect2, varscan2
- TBC1D31 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs375186187, COSV54866374; called by muse, mutect2, varscan2
- TBL2 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV59787109; called by muse, mutect2, varscan2
- TCF20 | c.4588C>T p.P1530S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV59492973; called by muse, mutect2, varscan2
- TCF23 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56078612; called by muse, mutect2, varscan2
- TCF4 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV61899412; called by muse, mutect2, varscan2
- TCN1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs978503152, COSV57252625, COSV57254628; called by muse, mutect2, varscan2
- TDRD6 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV60176500; called by muse, mutect2
- TENM3 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.958); catalogued as COSV69311369; called by muse, mutect2, varscan2
- TEX15 | c.257T>A p.I86K (on ENST00000256246; = p.I469K on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs771704901; called by muse, mutect2, varscan2
- TF | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395622; called by muse, mutect2, varscan2
- TGFBR1 | c.844T>G p.Y282D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM165737, COSV66626037; called by muse, varscan2
- THSD7B | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55703197; called by muse, mutect2, varscan2
- THSD7B | c.2885G>A p.G962D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747940; called by muse, mutect2, varscan2
- TMC5 | c.2243C>T p.S748F (on ENST00000396229 / NM_001105248.1; = p.S502F on NM_024780.5) | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54905654; called by muse, mutect2, varscan2
- TMEM132B | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as COSV54749780; called by muse, mutect2, varscan2
- TMEM161B | c.1348T>A p.F450I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56931674; called by muse, mutect2, varscan2
- TMEM200A | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51651568; called by muse, mutect2, varscan2
- TMEM38A | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as rs777182565, COSV51819594; called by muse, mutect2, varscan2
- TNFRSF9 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341665835, COSV66349047, COSV66349079; called by muse, mutect2, varscan2
- TNN | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428706; called by muse, mutect2, varscan2
- TNPO1 | c.1371T>G p.D457E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV61522316; called by muse, mutect2, varscan2
- TNR | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1490551355, COSV54892937; called by muse, mutect2, varscan2
- TPTE | c.1037G>A p.G346E (on ENST00000618007 / NM_199261.4; = p.G328E on NM_199259.4) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752996568; called by muse, mutect2, varscan2
- TPTE2 | c.1466G>A p.R489K (on ENST00000400230 / NM_199254.2; = p.R412K on NM_130785.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV55023300, COSV99690535; called by muse, mutect2, varscan2
- TRAK1 | c.2113A>T p.K705* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV59643991; called by muse, mutect2, varscan2
- TRANK1 | c.7281G>A p.W2427* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV57150997; called by muse, mutect2, varscan2
- TRAT1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55467290; called by muse, mutect2, varscan2
- TREML2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as COSV72439005; called by muse, mutect2, varscan2
- TRIM10 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64989795; called by muse, mutect2, varscan2
- TRIM13 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV53950019; called by muse, mutect2, varscan2
- TRPM1 | c.4636C>A p.P1546T | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV56636650; called by muse, mutect2
- TTC17 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768238865, COSV99235097; called by muse, mutect2, varscan2
- TTC17 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50008135; called by muse, mutect2, varscan2
- TTI1 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV65061988; called by muse, mutect2, varscan2
- TTLL5 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54036425; called by muse, mutect2, varscan2
- TTN | c.98265G>A p.W32755* (on ENST00000591111; = p.W25331* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV60140253; called by muse, mutect2, varscan2
- TTN | c.72425G>A p.R24142Q (on ENST00000591111; = p.R16718Q on NM_003319.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen possibly damaging (0.7); catalogued as rs777428147, COSV60036157, COSV60140345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.59962G>A p.E19988K (on ENST00000591111; = p.E12564K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs746364765, COSV60140394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNDC16 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV55984326, COSV55985306; called by muse, mutect2, varscan2
- UBN2 | c.3001T>A p.S1001T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV56032220; called by muse, mutect2, varscan2
- UGGT1 | c.450T>G p.F150L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV52137280; called by muse, mutect2, varscan2
- UGT3A1 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV57099308; called by muse, mutect2, varscan2
- UNC13C | c.6296G>A p.R2099K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52886778, COSV52899951; called by muse, mutect2, varscan2
- UNC93B1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57099615; called by muse, mutect2
- VCAN | c.9182C>T p.S3061F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.283); catalogued as COSV54108126; called by muse, mutect2
- VWA5A | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64411971; called by muse, mutect2, varscan2
- WASF2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV101420736, COSV71005828; called by muse, mutect2
- WDR36 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as COSV72605288; called by muse, mutect2
- WIZ | c.4586C>T p.A1529V (on ENST00000673675 / NM_001371589.1; = p.A434V on NM_021241.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.863); catalogued as COSV54608791; called by muse, mutect2, varscan2
- WWC1 | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs1439318547, COSV54652892; called by muse, mutect2, varscan2
- XAF1 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs1290507414, COSV60972262; called by muse, mutect2, varscan2
- XXYLT1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV59985153; called by muse, mutect2, varscan2
- YARS1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV65114306; called by muse, mutect2
- YBX2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV50301276; called by muse, mutect2, varscan2
- ZBTB20 | c.2035C>T p.R679* (on ENST00000474710 / NM_001164342.2; = p.R606* on NM_015642.6 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs1425346626, COSV61854649; called by muse, mutect2
- ZBTB26 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV65403500; called by muse, mutect2, varscan2
- ZFYVE26 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs773762160, COSV100720283; called by muse, mutect2, varscan2
- ZMIZ2 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV54809039; called by muse, mutect2, varscan2
- ZNF174 | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99237328; called by muse, mutect2, varscan2
- ZNF285 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV58409522; called by muse, mutect2, varscan2
- ZNF317 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.758); catalogued as rs1183411382, COSV56110269; called by muse, mutect2, varscan2
- ZNF430 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55110576; called by muse, mutect2, varscan2
- ZNF441 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV63540088; called by muse, mutect2, varscan2
- ZNF536 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as COSV62826509; called by muse, mutect2, varscan2
- ZNF610 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV58344115, COSV58345261; called by muse, mutect2, varscan2
- ZNF614 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54546845; called by muse, mutect2, varscan2
- ZNF683 | c.1330C>G p.H444D (on ENST00000403843; = p.H424D on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV62874718; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV58349648; called by muse, mutect2, varscan2
- ZNF99 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1334096852, COSV68055976; called by muse, mutect2, varscan2
- ZSCAN1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56604746; called by muse, mutect2, varscan2
- ARHGEF35 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by mutect2, varscan2
- EIF4G3 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- IGHV1OR21-1 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- LGALS3 | c.7_9del p.D3del | In Frame Del (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- LIMA1 | c.275del p.N92Tfs*17 | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | called by mutect2, pindel, varscan2
- TTN | c.5203G>A p.V1735M (on ENST00000591111; = p.V1689M on NM_003319.4) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ZKSCAN1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); called by muse, mutect2
- AAGAB | c.396C>T p.I132= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV56017297; called by muse, mutect2, varscan2
- AC011462.1 | c.489C>T p.S163= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV54197848; called by muse, mutect2
- AC097637.1 | c.402C>T p.S134= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV59726676; called by muse, mutect2, varscan2
- ACAN | c.6219C>T p.V2073= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1407423061, COSV61358824, COSV61362563; called by muse, mutect2
- ACSBG2 | c.255G>A p.Q85= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV99397319; called by muse, mutect2, varscan2
- ACTB | c.99C>T p.S33= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs749919451, COSV59317699; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACVR1C | c.426C>T p.S142= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV54647129; called by muse, mutect2, varscan2
- ADCY1 | c.3348G>A p.G1116= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV52034670; called by muse, mutect2, varscan2
- ADGRF1 | c.2361C>T p.I787= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV51946060; called by muse, mutect2, varscan2
- ADGRF5 | c.2856G>A p.T952= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs768306801, COSV51932529; called by muse, mutect2, varscan2
- AFDN | c.4560C>T p.A1520= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV60047192; called by muse, mutect2, varscan2
- AHNAK2 | c.2955C>T p.S985= | Silent (SNP) | VAF 70/342 reads (20%) | catalogued as COSV100316821; called by muse, varscan2
- ANAPC5 | c.2163C>T p.Y721= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV55843291; called by muse, mutect2, varscan2
- ANKRD24 | c.810C>T p.A270= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV53672015; called by muse, mutect2, varscan2
- APOB | c.3195A>G p.Q1065= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV51940154; called by muse, mutect2, varscan2
- APRT | c.451C>T p.L151= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV51936409; called by muse, mutect2, varscan2
- ARMCX2 | c.225C>T p.V75= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV57530487; called by muse, mutect2, varscan2
- ASXL2 | c.1371C>T p.F457= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as COSV55460778; called by muse, mutect2, varscan2
- ATP10D | c.3147G>A p.V1049= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56708890; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1065C>T p.T355= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52353995; called by muse, mutect2, varscan2
- ATP8B3 | c.3246C>T p.A1082= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100034279; called by muse, mutect2, varscan2
- B4GAT1 | c.1041C>T p.F347= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as COSV60820276; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2
- BMPR1B | c.1491C>T p.S497= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99215633, COSV99215944; called by muse, mutect2, varscan2
- BTBD7 | c.657C>T p.I219= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV54137007; called by muse, mutect2
- C1D | c.72C>T p.S24= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV63412996, COSV63413506; called by muse, mutect2, varscan2
- CACNA1G | c.2142G>A p.R714= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV61730587; called by muse, mutect2, varscan2
- CACNA2D1 | c.2859A>C p.R953= (on ENST00000356253 / NM_001366867.1; = p.R941= on NM_000722.4) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100666382; called by muse, mutect2, varscan2
- CASP4 | c.900C>T p.F300= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV67744534; called by muse, mutect2, varscan2
- CASZ1 | c.2781G>A p.Q927= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV59737200; called by muse, mutect2
- CD93 | c.1122G>A p.E374= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55666143; called by muse, mutect2, varscan2
- CEACAM19 | c.81C>T p.L27= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62552076; called by muse, mutect2, varscan2
- CEP162 | c.3111C>T p.A1037= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100002611; called by muse, mutect2, varscan2
- CEP57L1 | c.1134C>T p.I378= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV61245076; called by muse, mutect2, varscan2
- CHRD | c.2403C>T p.P801= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs144610754, COSV52606649; called by muse, mutect2, varscan2
- CHST5 | c.696C>T p.S232= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV60340006; called by muse, mutect2, varscan2
- CIPC | c.264C>T p.T88= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1359656384, COSV62377106; called by muse, mutect2, varscan2
- CNOT3 | c.685C>T p.L229= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV55364643; called by muse, mutect2, varscan2
- CNTN2 | c.192G>A p.R64= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs140395973; called by muse, mutect2, varscan2
- CNTNAP2 | c.2259G>A p.R753= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV62201712; called by muse, mutect2, varscan2
- COL4A5 | c.3690C>T p.F1230= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV60364132; called by muse, mutect2, varscan2
- COL9A1 | c.687T>A p.V229= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV61833960; called by muse, mutect2, varscan2
- CTAGE1 | c.1404A>G p.E468= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV66943786; called by muse, mutect2, varscan2
- CTRC | c.204C>T p.F68= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs773793601, COSV65621345; called by muse, mutect2, varscan2
- DCANP1 | c.633C>T p.S211= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs764714089, COSV72345845; called by muse, mutect2, varscan2
- DDX60 | c.4831C>T p.L1611= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV67097365; called by muse, mutect2
- DEFA6 | c.210C>T p.F70= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1002623522, COSV52406190; called by muse, mutect2, varscan2
- DGKI | c.1392G>A p.G464= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV55956395; called by muse, mutect2, varscan2
- DNAH8 | c.2085A>G p.Q695= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV59456004; called by muse, mutect2, varscan2
- DRAM2 | c.423C>T p.I141= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV54415759; called by muse, mutect2
- DUOX2 | c.3867C>T p.F1289= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV66532738; called by muse, mutect2, varscan2
- EDA | c.987C>T p.F329= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV65780025; called by muse, mutect2
- EHD1 | c.1017C>T p.Y339= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57735259; called by muse, mutect2, varscan2
- EIF4G3 | c.1548C>T p.T516= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs371798270; called by muse, mutect2, varscan2
- ELANE | c.231C>T p.V77= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1211839395, CD135419, COSV55048336; called by muse, mutect2
- EPHA4 | c.2256C>T p.I752= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56036546; called by muse, mutect2, varscan2
- ETFA | c.859T>C p.L287= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV51211735; called by muse, mutect2, varscan2
- ETNK1 | c.192C>T p.G64= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56886682; called by muse, mutect2, varscan2
- F13B | c.441G>A p.R147= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV66374418; called by muse, mutect2, varscan2
- FAM177B | c.78C>T p.I26= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs140872706; called by muse, mutect2, varscan2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- FAT1 | c.10689C>T p.V3563= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs779298419, COSV71674723; called by muse, mutect2, varscan2
- FAT4 | c.612C>T p.S204= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV67890006; called by muse, mutect2, varscan2
- FBN2 | c.3834G>A p.G1278= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV52521907; called by muse, mutect2, varscan2
- FCGBP | c.7056G>A p.G2352= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- FCRL5 | c.2733G>T p.V911= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV62514047; called by muse, mutect2, varscan2
- FER1L6 | c.2295G>A p.G765= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV67550774; called by muse, mutect2, varscan2
- FLRT1 | c.138G>A p.T46= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs759918242, COSV55365861; called by mutect2, varscan2
- FOXI2 | c.819G>A p.G273= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1386614054, COSV59094592; called by muse, mutect2, varscan2
- FREM1 | c.1725G>A p.G575= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV66525409; called by muse, mutect2, varscan2
- G3BP1 | c.24C>T p.P8= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100663926; called by muse, mutect2, varscan2
- G3BP1 | c.25C>T p.L9= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs1561532855, COSV100663927; called by muse, mutect2, varscan2
- GALNT9 | c.1179C>T p.A393= (on ENST00000328957 / NM_001122636.2; = p.A27= on NM_021808.3) | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs369757893; called by muse, varscan2
- GAS6 | c.1176C>T p.V392= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV59851869; called by muse, mutect2, varscan2
- GASK1B | c.372C>G p.T124= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs746162799, COSV56708219, COSV99647406; called by muse, mutect2, varscan2
- GLI1 | c.840G>A p.R280= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV57363679; called by muse, mutect2, varscan2
- GLIS1 | c.264C>T p.S88= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV56550442; called by muse, mutect2, varscan2
- GLUD2 | c.297G>A p.R99= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV60152184; called by muse, mutect2, varscan2
- GPR119 | c.273C>T p.A91= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99358592; called by muse, mutect2, varscan2
- GRIN2A | c.324C>T p.A108= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs762110435, COSV58039618; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.942C>T p.I314= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV74206439; called by muse, mutect2, varscan2
- GRK5 | c.1458G>A p.V486= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV64866731; called by muse, mutect2, varscan2
- GSTM4 | c.474C>T p.F158= | Silent (SNP) | VAF 106/395 reads (27%) | catalogued as rs746341335, COSV100264064; called by muse, mutect2, varscan2
- GTF2IRD1 | c.549C>T p.P183= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99734408; called by muse, mutect2
- HELZ2 | c.6438C>T p.I2146= (on ENST00000467148 / NM_001037335.2; = p.I1577= on NM_033405.3) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101427544; called by muse, mutect2, varscan2
- HIVEP1 | c.3909C>T p.S1303= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV65102626; called by muse, mutect2, varscan2
- HOXC12 | c.267G>A p.E89= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54535272; called by muse, mutect2, varscan2
- HPSE | c.546G>A p.L182= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV60987334; called by muse, mutect2, varscan2
- HTR4 | c.867C>T p.V289= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100087661; called by muse, mutect2, varscan2
- ICAM4 | c.681C>T p.P227= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV53425554; called by muse, mutect2, varscan2
- IGF1R | c.933C>T p.F311= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- IGHG3 | c.615C>T p.F205= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as rs761397793; called by muse, mutect2, varscan2
- IGHV1-45 | c.273G>A p.R91= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- INSIG1 | c.273C>T p.L91= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV60920611; called by muse, mutect2
- ITPKB | c.2277C>T p.A759= | Silent (SNP) | VAF 71/206 reads (34%) | catalogued as COSV55263836; called by muse, mutect2, varscan2
- KANK2 | c.405C>T p.L135= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs781246871, COSV62008322; called by muse, mutect2, varscan2
- KATNIP | c.4089C>T p.F1363= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as rs202117354, COSV55183606; called by muse, mutect2, varscan2
- KCNMB1 | c.498C>T p.F166= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV51132887; called by muse, mutect2, varscan2
- KIAA1614 | c.2874C>T p.S958= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs1426453800, COSV100851183; called by muse, mutect2
- KIAA1614 | c.2875C>T p.L959= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100851184; called by muse, mutect2
- KIF1A | c.2947C>T p.L983= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV57492851; called by muse, mutect2
- KRT20 | c.420G>A p.R140= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs769153459, COSV51425216; called by muse, mutect2, varscan2
- KRT38 | c.219C>T p.C73= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs201850909, COSV55846446; called by muse, varscan2
- LCT | c.1173C>T p.S391= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV51551683; called by muse, mutect2, varscan2
- MACROD2 | c.513C>T p.L171= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs758153923, COSV54002118; called by muse, mutect2, varscan2
- MAGEB6 | c.720C>T p.T240= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1261846187, COSV66871755; called by muse, mutect2, varscan2
- MAGEC1 | c.1675C>T p.L559= | Silent (SNP) | VAF 139/258 reads (54%) | catalogued as COSV53575216; called by muse, mutect2, varscan2
- MAGEH1 | c.240C>T p.P80= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV61678876; called by muse, mutect2, varscan2
- MAN1B1 | c.1656C>A p.L552= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV65371466; called by muse, mutect2
- MAN2B1 | c.1605C>T p.F535= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs1421304561, COSV55471383; called by muse, mutect2, varscan2
- MARVELD3 | c.513A>T p.G171= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99194810; called by muse, mutect2, varscan2
- MATN2 | c.1023C>T p.S341= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV54713456; called by muse, mutect2, varscan2
- MBD6 | c.2781G>A p.K927= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV63075207; called by muse, mutect2, varscan2
- MCM3AP | c.2691C>T p.T897= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs773035448, COSV52441155; called by muse, mutect2, varscan2
- MDM4 | c.592C>T p.L198= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV65796056; called by muse, mutect2, varscan2
- MEF2A | c.619T>C p.L207= (on ENST00000557942 / NM_001319206.2; = p.L209= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV57534715; called by muse, mutect2, varscan2
- MFSD11 | c.912T>G p.R304= | Silent (SNP) | VAF 65/206 reads (32%) | catalogued as COSV60625104; called by muse, mutect2, varscan2
- MIEF2 | c.837C>T p.I279= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59902082; called by muse, mutect2, varscan2
- MTOR | c.451C>A p.R151= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100816729, COSV63873194; called by muse, mutect2
- MUC16 | c.20868C>T p.T6956= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV67474574, COSV67488594; called by muse, mutect2, varscan2
- MYH4 | c.5244C>T p.I1748= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs149221663; called by muse, mutect2, varscan2
- MYO19 | c.1506C>T p.L502= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- NBEA | c.5121G>A p.L1707= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV59794784; called by muse, mutect2, varscan2
- NEB | c.16971G>A p.K5657= | Silent (SNP) | VAF 36/195 reads (18%) | catalogued as COSV51427464; called by muse, mutect2, varscan2
- NEFL | c.1560C>T p.T520= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs267607677, COSV55337376, COSV99648128; called by muse, mutect2, varscan2
- NEURL4 | c.1665G>A p.L555= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs375039727; called by muse, mutect2, varscan2
- NEUROD4 | c.783G>A p.G261= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV54470956; called by muse, mutect2, varscan2
- NIBAN3 | c.1581C>T p.I527= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56310385; called by muse, mutect2
- NLRC4 | c.927C>T p.I309= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100707328; called by muse, mutect2, varscan2
- NLRP1 | c.966G>A p.L322= | Silent (SNP) | VAF 62/245 reads (25%) | catalogued as COSV52569051; called by muse, mutect2, varscan2
- NLRP12 | c.2034G>A p.A678= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1480988371, COSV60749407; called by muse, mutect2
- NLRP2 | c.1698C>T p.A566= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV54756500, COSV99672212; called by muse, mutect2, varscan2
- NPY2R | c.498C>T p.F166= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV61527301; called by muse, mutect2, varscan2
- OBSCN | c.3468C>T p.H1156= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs1180577013, COSV99475948; called by muse, mutect2, varscan2
- OBSCN | c.3469C>T p.L1157= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs1042859324, COSV99475952; called by muse, mutect2, varscan2
- OGDHL | c.1696C>T p.L566= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV65103171, COSV65104731; called by muse, mutect2, varscan2
- OPCML | c.463C>T p.L155= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100099776; called by muse, mutect2
- OPCML | c.462C>T p.T154= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV59419919; called by muse, mutect2
- OR10A3 | c.676C>T p.L226= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV62459702; called by muse, mutect2, varscan2
- OR10H2 | c.204C>T p.V68= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV59946262; called by muse, mutect2, varscan2
- OR10J5 | c.93C>T p.F31= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs748213019, COSV58384961; called by muse, mutect2, varscan2
- OR10K2 | c.283C>T p.L95= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV59221047; called by muse, mutect2, varscan2
- OR51A7 | c.882G>A p.K294= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV63788536; called by muse, mutect2, varscan2
- OR51E2 | c.72C>T p.F24= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs891465916, COSV101211400, COSV67807769; called by muse, mutect2, varscan2
- OR52E8 | c.177G>A p.Q59= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV66207668, COSV66211831; called by muse, mutect2, varscan2
- OTOGL | c.4905G>A p.Q1635= (on ENST00000547103; = p.Q1626= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs764127848, COSV54018438; called by muse, mutect2, varscan2
- PALMD | c.1251C>T p.F417= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54165150, COSV99586456; called by muse, mutect2, varscan2
- PASD1 | c.2283G>A p.L761= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV64855819; called by muse, mutect2, varscan2
- PCDHGA2 | c.2310C>T p.F770= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV53969375, COSV99545694; called by muse, mutect2, varscan2
- PCDHGB3 | c.663C>T p.S221= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV53969389, COSV53981644; called by muse, mutect2, varscan2
- PCLO | c.2220C>T p.V740= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV61642935; called by muse, mutect2, varscan2
- PDE1C | c.270G>A p.Q90= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV68803371, COSV68812355; called by muse, mutect2, varscan2
- PEPD | c.378C>T p.V126= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV54891749; called by muse, mutect2, varscan2
- PHC2 | c.1704C>T p.I568= (on ENST00000257118 / NM_198040.2; = p.I33= on NM_004427.4) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV57105351; called by muse, mutect2
- PIGQ | c.525C>T p.L175= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV50315250; called by muse, mutect2
- PKDREJ | c.1764G>A p.R588= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs1337352124, COSV53550077; called by muse, mutect2, varscan2
- PLCB3 | c.585C>T p.L195= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV54189556; called by muse, mutect2
- PLEKHH2 | c.3801G>A p.E1267= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56756240; called by muse, mutect2, varscan2
- PLEKHM3 | c.1479C>T p.S493= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV66817066; called by muse, mutect2, varscan2
- PMEPA1 | c.342G>A p.R114= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- PPCDC | c.588C>T p.F196= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV61625371; called by muse, mutect2, varscan2
- PPP1R12B | c.1869A>C p.V623= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51786107; called by muse, varscan2
- PRAMEF19 | c.1056G>A p.Q352= | Silent (SNP) | VAF 46/522 reads (9%) | catalogued as COSV101069388; called by muse, mutect2
- PRCP | c.1333C>T p.L445= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV57289439; called by muse, mutect2
- PRDM10 | c.2421C>T p.L807= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV58800179; called by muse, mutect2, varscan2
- PRDM15 | c.723C>T p.G241= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1185438080, COSV54154662; called by muse, varscan2
- PRDM5 | c.1380G>A p.K460= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV53362251; called by muse, mutect2, varscan2
- PREPL | c.1920G>A p.T640= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs747712512, COSV53217421; called by muse, mutect2, varscan2
- PSMF1 | c.783C>T p.L261= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs750512137, COSV55674478; called by muse, mutect2
- PTOV1 | c.642C>T p.F214= | Silent (SNP) | VAF 61/292 reads (21%) | catalogued as COSV55588644, COSV55590338; called by muse, mutect2, varscan2
- PTPRH | c.2487G>A p.L829= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV54746653; called by muse, mutect2
- RBM22 | c.6G>A p.A2= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52272135; called by muse, mutect2, varscan2
- RBM27 | c.1431C>A p.T477= | Silent (SNP) | VAF 52/195 reads (27%) | catalogued as COSV99505988; called by muse, mutect2, varscan2
- RESF1 | c.2487C>T p.T829= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57023084; called by muse, mutect2, varscan2
- RFTN2 | c.388C>T p.L130= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV54389547, COSV99695346; called by muse, mutect2, varscan2
- ROBO1 | c.4248G>A p.L1416= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV71392447, COSV71395873; called by muse, mutect2, varscan2
- ROGDI | c.673C>T p.L225= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- RPGRIP1L | c.1816C>T p.L606= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV50908800; called by muse, mutect2, varscan2
- RPS4X | c.495G>A p.E165= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV60181725; called by muse, mutect2, varscan2
- RTN3 | c.1950C>T p.S650= (on ENST00000377819 / NM_001265589.2; = p.S631= on NM_201428.3) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100380045; called by muse, mutect2, varscan2
- RYR2 | c.6321G>A p.T2107= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs764476121, COSV100772088, COSV63684440; ClinVar: likely benign; called by muse, mutect2, varscan2
- SASH1 | c.2149C>T p.L717= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV66562741; called by muse, mutect2, varscan2
- SCAF11 | c.3918T>C p.S1306= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1289757919, COSV65477218; called by muse, mutect2
- SCYL3 | c.469C>T p.L157= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV63046307; called by muse, mutect2, varscan2
- SEMG1 | c.819C>T p.L273= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV99725173; called by muse, mutect2, varscan2
- SETD1A | c.612C>T p.F204= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV52689140; called by muse, mutect2, varscan2
- SH2D4B | c.213C>T p.L71= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV57897008; called by muse, mutect2, varscan2
- SLC10A1 | c.90C>T p.I30= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV53682843; called by muse, mutect2, varscan2
- SLC13A2 | c.75G>A p.L25= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58995985; called by muse, mutect2, varscan2
- SLC14A2 | c.672G>A p.L224= | Silent (SNP) | VAF 80/319 reads (25%) | catalogued as COSV54910338; called by muse, mutect2, varscan2
- SLC18A1 | c.96C>T p.L32= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV52348853; called by muse, mutect2, varscan2
- SLC22A6 | c.1110C>T p.I370= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV64560383; called by muse, mutect2, varscan2
- SLC22A8 | c.213G>A p.E71= | Silent (SNP) | VAF 35/199 reads (18%) | catalogued as COSV60325659; called by muse, mutect2, varscan2
- SLC26A8 | c.2175C>T p.I725= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV62886283, COSV62887075; called by muse, mutect2, varscan2
- SLC35A5 | c.1068C>T p.S356= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1217218625, COSV53727156; called by muse, mutect2, varscan2
- SLC35G2 | c.384G>A p.R128= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV67588513; called by muse, mutect2, varscan2
- SLC9A1 | c.2256T>C p.A752= | Silent (SNP) | VAF 60/213 reads (28%) | catalogued as COSV56054305; called by muse, mutect2, varscan2
- SLC9C1 | c.1368C>T p.A456= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99997689; called by muse, mutect2
- SMARCAD1 | c.2958C>T p.S986= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV62774916; called by muse, mutect2
- SNAI2 | c.12C>T p.S4= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV50079354; called by muse, mutect2, varscan2
- SPAG17 | c.5994A>G p.K1998= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs1274296047, COSV60461307; called by muse, mutect2, varscan2
- SPTBN1 | c.5676C>T p.A1892= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV61689680; called by muse, mutect2, varscan2
- ST6GAL2 | c.456C>T p.S152= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs780773564, COSV64529274; called by muse, mutect2
- STK17B | c.987C>T p.S329= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs540299725, COSV55828789, COSV99826264; called by muse, mutect2
- STK19 | c.966C>T p.L322= (on ENST00000375333 / NM_032454.1; = p.L318= on NM_004197.1) | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs769028359, COSV64692466; called by muse, mutect2, varscan2
- SULF2 | c.1333C>T p.L445= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1426418822, COSV100737383, COSV63417274; called by muse, mutect2
- SULT2A1 | c.558G>A p.E186= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV55765280; called by muse, mutect2, varscan2
- SUPT6H | c.1785G>A p.Q595= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58928403; called by muse, mutect2, varscan2
- SZT2 | c.6721C>T p.L2241= (on ENST00000634258 / NM_001365999.1; = p.L2184= on NM_015284.4) | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV65170918; called by muse, mutect2, varscan2
- TASOR | c.4780T>C p.L1594= (on ENST00000355628 / NM_001365636.2; = p.L1218= on NM_015224.3) | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV58305262; called by muse, mutect2
- TBC1D21 | c.738T>A p.R246= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100311267; called by muse, mutect2
- TBL2 | c.501C>T p.T167= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99979560; called by muse, mutect2, varscan2
- TCF19 | c.951C>T p.F317= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV52564083; called by muse, mutect2, varscan2
- TCN1 | c.1260C>T p.V420= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV99953199; called by muse, mutect2
- TENM1 | c.6594C>T p.L2198= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs768909492, COSV100949646; called by muse, mutect2, varscan2
- TEX15 | c.3951C>T p.F1317= (on ENST00000256246; = p.F1700= on NM_001350162.2) | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV56348125; called by muse, mutect2, varscan2
- TF | c.1446C>T p.P482= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs568524319, COSV99395624; called by muse, mutect2, varscan2
- TFR2 | c.1395C>T p.F465= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV56154829; called by muse, mutect2, varscan2
- TIPRL | c.255G>A p.V85= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV63207925; called by muse, mutect2, varscan2
- TMTC1 | c.612C>T p.F204= (on ENST00000539277 / NM_001193451.2; = p.F96= on NM_175861.3) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV55484723; called by muse, mutect2, varscan2
- TOPBP1 | c.3747C>T p.H1249= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53437374; called by muse, mutect2, varscan2
- TP53I3 | c.930C>A p.I310= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV51981184; called by muse, varscan2
- TP63 | c.1872T>C p.S624= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV53209525; called by muse, mutect2, varscan2
- TRIM58 | c.495G>A p.G165= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV63570850; called by muse, mutect2, varscan2
- TRPC3 | c.660C>T p.F220= (on ENST00000379645 / NM_001366479.2; = p.F147= on NM_003305.2) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53376961; called by muse, mutect2, varscan2
- TRPC5 | c.1836C>T p.S612= | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as COSV53293827, COSV53299025; called by muse, mutect2, varscan2
- TRPM1 | c.4638A>C p.P1546= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV56636639; called by muse, mutect2
- TTN | c.78081G>A p.E26027= (on ENST00000591111; = p.E18603= on NM_003319.4) | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as COSV60140303; called by muse, mutect2, varscan2
- TTN | c.33639A>G p.K11213= (on ENST00000591111; = p.K10286= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV59881088, COSV60140429; called by muse, mutect2, varscan2
- TTN | c.14970C>T p.Y4990= (on ENST00000591111; = p.Y4063= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60041985; called by muse, mutect2, varscan2
- VAMP3 | c.105G>A p.K35= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV50012663; called by muse, mutect2, varscan2
- VPS13C | c.8019G>A p.R2673= (on ENST00000644861 / NM_020821.3; = p.R2630= on NM_017684.5) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV51263902, COSV99829073; called by muse, mutect2
- WDFY3 | c.5883C>T p.F1961= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs375780380, COSV55697270; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1356C>T p.S452= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV56273245; called by muse, mutect2, varscan2
- ZNF174 | c.567C>T p.P189= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV99237331; called by muse, mutect2, varscan2
- ZNF407 | c.435G>T p.L145= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs562887940, COSV99996762; called by muse, mutect2, varscan2
- ZNF512B | c.1458C>T p.A486= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV53872567; called by muse, mutect2, varscan2
- ZNF518B | c.2673C>T p.T891= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV58723113; called by muse, mutect2, varscan2
- ZNF594 | c.2223C>G p.T741= | Silent (SNP) | VAF 39/208 reads (19%) | catalogued as rs756289611, COSV101280584, COSV68385602, COSV68385708; called by muse, mutect2, varscan2
- ZNF641 | c.324G>A p.L108= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56390601; called by muse, mutect2, varscan2
- ZNF695 | c.1056C>T p.F352= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV60586343; called by muse, mutect2
- ZNF764 | c.568C>T p.L190= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53221901; called by muse, mutect2, varscan2
- ZSCAN1 | c.714C>T p.P238= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56602050; called by muse, mutect2, varscan2
- BEND6 | chr6:56954453 C>T | 5'Flank (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- BEND6 | chr6:56954454 C>T | 5'Flank (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- BOLA3 | c.*50C>T | 3'UTR (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99768133; called by muse, mutect2
- CLEC14A | c.*2G>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100643455; called by muse, mutect2
- CLLU1 | chr12:92421030 C>T | 5'Flank (SNP) | VAF 83/302 reads (27%) | catalogued as rs894353074, COSV65903168; called by muse, mutect2, varscan2
- FGFR3 | c.*859G>T | 3'UTR (SNP) | VAF 24/96 reads (25%) | catalogued as COSV53405729; called by muse, mutect2, varscan2
- MAML3 | c.2079+156C>T | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as rs762146821, COSV100505109; called by muse, mutect2, varscan2
- NXF5 | n.1537C>T | RNA (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99534254; called by muse, mutect2, varscan2
- PHACTR1 | c.664+2125G>A | Intron (SNP) | VAF 24/128 reads (19%) | catalogued as COSV100276422; called by muse, mutect2, varscan2
- PTPRN2 | c.113-42992A>T | Intron (SNP) | VAF 28/110 reads (25%) | catalogued as COSV101133240; called by muse, mutect2, varscan2
- SSPOP | n.8762C>T | RNA (SNP) | VAF 8/67 reads (12%) | catalogued as rs757397010, COSV65131918; called by muse, mutect2, varscan2
- SSPOP | n.11752G>A | RNA (SNP) | VAF 11/54 reads (20%) | catalogued as COSV65131922; called by muse, mutect2, varscan2
- SSX9P | n.292G>A | RNA (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7468C>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- TTI2 | chr8:33513526 A>T | 5'Flank (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100659670; called by muse, mutect2, varscan2
- USH1C | c.1284+1117G>A | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99139715; called by muse, mutect2, varscan2
- WT1 | c.965+1070G>A | Intron (SNP) | VAF 53/350 reads (15%) | catalogued as COSV60074336; called by muse, mutect2, varscan2
- ZFHX3 | c.-863C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1241477780; called by muse, mutect2
